Somatic mutation profile of tumor specimen HCM-SANG-0270-C20-01B (aliquot HCM-SANG-0270-C20-01B-01D-A79M-36) from HCMI case HCM-SANG-0270-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Tumor grade: G2.
Specimen HCM-SANG-0270-C20-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09aed12a-76b9-4fef-8e77-b1362c99c52d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0270-C20-10B (Blood Derived Normal), aliquot HCM-SANG-0270-C20-10B-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b312b577-c463-4a8f-bbc2-4f9350a3daf8

The open-access MAF lists 128 somatic variants for this specimen: 96 protein-altering or splice-affecting, 25 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 92, Silent 25, Intron 4, Frame Shift Del 2, Frame Shift Ins 1, 5'UTR 1, Splice Site 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 237/372 reads (64%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 93/327 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 196/375 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80338963, CD147870, CM040450, CM041789, CM981228, COSV61683972, COSV61685418, COSV61686083; ClinVar: likely pathogenic / not provided / pathogenic; called by muse, mutect2, varscan2
- ABHD12B | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 140/445 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs1392372319; called by muse, mutect2, varscan2
- ACACA | c.1705C>T p.R569C | Missense Mutation (SNP) | VAF 118/390 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs145246486; called by muse, mutect2, varscan2
- ACACB | c.2087C>T p.A696V | Missense Mutation (SNP) | VAF 95/378 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs773666938, COSV58131696; called by muse, mutect2, varscan2
- ACADL | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 109/344 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.46); catalogued as rs546101555; called by muse, mutect2, varscan2
- ADAM29 | c.1728C>A p.F576L | Missense Mutation (SNP) | VAF 118/391 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.096); catalogued as COSV100822047; called by muse, mutect2, varscan2
- ANHX | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 76/283 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.625); catalogued as rs1480651088, COSV101376525; called by muse, mutect2, varscan2
- APCDD1 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 138/580 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.479); catalogued as rs201834801; called by muse, mutect2, varscan2
- ARID1A | c.5548dup p.D1850Gfs*4 | Frame Shift Ins (INS) | VAF 118/403 reads (29%) | catalogued as rs758608743; called by mutect2, varscan2
- ATF7IP | c.2522C>T p.P841L | Missense Mutation (SNP) | VAF 14/412 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.76); catalogued as COSV53773909; called by muse, mutect2
- ATG2A | c.5656G>A p.V1886M | Missense Mutation (SNP) | VAF 183/624 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765776372; called by muse, mutect2, varscan2
- AZI2 | c.1052T>C p.F351S | Missense Mutation (SNP) | VAF 90/324 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as rs1354201699; called by muse, mutect2, varscan2
- BCL11A | c.1498G>A p.V500M (on ENST00000335712 / NM_001365609.1; = p.V534M on NM_018014.4) | Missense Mutation (SNP) | VAF 161/713 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.106); catalogued as rs773235162, COSV100186570; called by muse, mutect2, varscan2
- BOP1 | c.691G>A p.V231I | Missense Mutation (SNP) | VAF 373/915 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs1383645232; called by muse, mutect2, varscan2
- C2orf42 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 66/302 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1388504707; called by muse, mutect2, varscan2
- CAD | c.6190C>T p.R2064C | Missense Mutation (SNP) | VAF 13/397 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53023698, COSV53029560; called by muse, mutect2
- CCDC77 | c.92G>A p.R31K | Missense Mutation (SNP) | VAF 19/388 reads (5%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as COSV53472243, COSV53473048; called by muse, mutect2
- CEP164 | c.4174C>T p.R1392W | Missense Mutation (SNP) | VAF 63/187 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs769676851, COSV99632450; called by muse, mutect2, varscan2
- CHD4 | c.2831G>A p.R944Q (on ENST00000357008 / NM_001363606.2; = p.R957Q on NM_001273.5) | Missense Mutation (SNP) | VAF 142/442 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs76359472, COSV104399234, COSV58904513; called by muse, mutect2, varscan2
- CHMP1A | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 81/353 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.335); catalogued as rs200323717; called by muse, mutect2, varscan2
- DACT2 | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 247/568 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748077283; called by muse, mutect2, varscan2
- DSG1 | c.2135G>A p.R712H | Missense Mutation (SNP) | VAF 20/322 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as rs372022015; called by muse, mutect2
- F13B | c.404G>A p.C135Y | Missense Mutation (SNP) | VAF 99/309 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66376011; called by muse, mutect2, varscan2
- FST | c.344G>T p.R115L | Missense Mutation (SNP) | VAF 187/314 reads (60%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs1177495235; called by muse, mutect2, varscan2
- GABRD | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 73/574 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs749014692; called by muse, mutect2, varscan2
- GRIK1 | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 129/399 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs373016584; called by muse, mutect2, varscan2
- H2BC1 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 150/357 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.931); catalogued as rs1351937593, COSV51236761; called by muse, mutect2, varscan2
- HEXIM2 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 119/526 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as rs1267872165; called by muse, mutect2, varscan2
- IDO2 | c.133G>A p.E45K (on ENST00000389060; = p.E58K on NM_194294.2) | Missense Mutation (SNP) | VAF 19/482 reads (4%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.721); catalogued as rs1273301377, COSV58427614; called by muse, mutect2
- ILDR2 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 87/368 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs937233990, COSV54833776; called by muse, mutect2, varscan2
- ITIH5 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 160/403 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs759497987, COSV56909484; called by muse, mutect2, varscan2
- KCNT1 | c.1366G>A p.A456T (on ENST00000488444; = p.A475T on NM_020822.3) | Missense Mutation (SNP) | VAF 72/498 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.115); catalogued as rs144956052; called by muse, mutect2, varscan2
- KIF23 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 61/224 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as rs756964640, COSV52980273; called by muse, mutect2, varscan2
- KLHL6 | c.1781G>A p.R594Q | Missense Mutation (SNP) | VAF 37/640 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV58067455; called by muse, mutect2
- LAMA4 | c.1447G>T p.A483S (on ENST00000230538 / NM_001105206.3; = p.A476S on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 103/392 reads (26%) | SIFT tolerated (0.84); PolyPhen benign (0.096); catalogued as COSV57903863; called by muse, mutect2, varscan2
- LRRC49 | c.251C>G p.S84C | Missense Mutation (SNP) | VAF 60/232 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); catalogued as rs150271201; called by muse, mutect2, varscan2
- MAGI2 | c.2671G>A p.A891T | Missense Mutation (SNP) | VAF 63/521 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs1052002858, COSV62641530; called by muse, mutect2, varscan2
- MCM10 | c.154G>A p.G52S | Missense Mutation (SNP) | VAF 105/479 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.152); catalogued as rs753259372, COSV66333608; called by muse, mutect2, varscan2
- MPHOSPH9 | c.2963C>T p.S988F | Missense Mutation (SNP) | VAF 21/449 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1348474455; called by muse, mutect2
- MYBPC3 | c.3277G>A p.G1093S | Missense Mutation (SNP) | VAF 149/448 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs727503173; called by muse, mutect2, varscan2
- NLGN4X | c.2103C>A p.D701E | Missense Mutation (SNP) | VAF 48/380 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.751); catalogued as COSV99320586; called by muse, mutect2, varscan2
- NLRP4 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 121/412 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.307); catalogued as rs772979970; called by muse, mutect2, varscan2
- NOTCH2 | c.5105G>A p.R1702Q | Missense Mutation (SNP) | VAF 91/283 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs999822357, COSV56709641; called by muse, mutect2, varscan2
- NOTCH4 | c.2401C>T p.R801C | Missense Mutation (SNP) | VAF 20/682 reads (3%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.828); catalogued as rs369297005; called by muse, mutect2
- NRXN1 | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 110/358 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs372823663; called by muse, mutect2, varscan2
- NTRK3 | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 154/498 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.019); catalogued as rs183806623, COSV100448367, COSV58112677, COSV58116202; called by muse, mutect2, varscan2
- NUP160 | c.3719C>T p.T1240M | Missense Mutation (SNP) | VAF 86/294 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as rs535059681, COSV65854418; called by muse, mutect2, varscan2
- OR4N2 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 130/818 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs201108157, COSV60050074; called by muse, mutect2, varscan2
- OR51E2 | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 119/373 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.081); catalogued as rs142195646, COSV101211306; called by muse, mutect2, varscan2
- OR5J2 | c.429G>T p.E143D | Missense Mutation (SNP) | VAF 100/338 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV56623841; called by muse, varscan2
- PDE8B | c.1813G>A p.E605K | Missense Mutation (SNP) | VAF 24/469 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53731954; called by muse, mutect2
- PKHD1L1 | c.7336C>T p.P2446S | Missense Mutation (SNP) | VAF 67/354 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs1343952887; called by muse, mutect2, varscan2
- PQBP1 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 112/538 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.207); catalogued as rs782506693; called by muse, mutect2, varscan2
- PRM1 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 94/327 reads (29%) | PolyPhen probably damaging (0.928); catalogued as rs374230515; called by muse, mutect2, varscan2
- SERPINF1 | c.715G>A p.V239M | Missense Mutation (SNP) | VAF 122/425 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs376520683; called by muse, mutect2, varscan2
- SIGLEC12 | c.1447G>A p.G483R (on ENST00000291707 / NM_053003.4; = p.G365R on NM_033329.2) | Missense Mutation (SNP) | VAF 55/208 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.344); catalogued as rs372236004; called by muse, mutect2, varscan2
- SNAPC2 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 164/566 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.699); catalogued as rs1009937630, COSV55604301; called by muse, mutect2, varscan2
- SRSF7 | c.381A>C p.R127S | Missense Mutation (SNP) | VAF 62/224 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs148174608; called by muse, varscan2
- SUPT6H | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 13/345 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV58927022, COSV58928664; called by muse, mutect2
- SVOP | c.1328C>T p.A443V | Missense Mutation (SNP) | VAF 11/300 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.206); catalogued as rs970863003; called by muse, mutect2
- TMEM225 | c.118G>T p.D40Y | Missense Mutation (SNP) | VAF 128/478 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.578); catalogued as COSV66693732; called by muse, mutect2, varscan2
- TMTC1 | c.187G>A p.V63M | Missense Mutation (SNP) | VAF 35/863 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1204335569; called by muse, mutect2
- TRPA1 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 48/393 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.288); catalogued as COSV51555755; called by muse, mutect2, varscan2
- ANO4 | c.1078A>T p.M360L (on ENST00000392977 / NM_001286615.2; = p.M325L on NM_178826.4) | Missense Mutation (SNP) | VAF 133/393 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- APOB | c.4055T>C p.L1352P | Missense Mutation (SNP) | VAF 16/482 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CTNNB1 | c.533T>G p.L178R | Missense Mutation (SNP) | VAF 163/265 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CYP1B1 | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 205/735 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- DCLK1 | c.557A>T p.K186M | Missense Mutation (SNP) | VAF 66/344 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- DENND11 | c.607C>A p.P203T | Missense Mutation (SNP) | VAF 26/694 reads (4%) | SIFT tolerated (0.6); PolyPhen benign (0.015); called by muse, mutect2
- FIZ1 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 146/634 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- GOLGA8K | c.1217C>G p.A406G | Missense Mutation (SNP) | VAF 16/249 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.236); called by muse, mutect2
- GSDMC | c.570+1G>C p.X190_splice | Splice Site (SNP) | VAF 115/236 reads (49%) | called by muse, mutect2, varscan2
- HMCN1 | c.8724A>C p.K2908N | Missense Mutation (SNP) | VAF 15/349 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- HS3ST5 | c.611A>G p.N204S | Missense Mutation (SNP) | VAF 183/472 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- LAS1L | c.1225T>G p.L409V | Missense Mutation (SNP) | VAF 22/622 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- MRPL54 | c.347A>G p.E116G | Missense Mutation (SNP) | VAF 28/588 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2
- MYOF | c.3821A>C p.K1274T | Missense Mutation (SNP) | VAF 12/291 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.384); called by muse, mutect2
- NFIB | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 214/469 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NHS | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 203/644 reads (32%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDH17 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 102/570 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- PCDHB1 | c.1637T>G p.V546G | Missense Mutation (SNP) | VAF 11/370 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2
- PCDHB4 | c.901C>A p.L301M | Missense Mutation (SNP) | VAF 49/260 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- PIK3R1 | c.460_461del p.S154Lfs*12 | Frame Shift Del (DEL) | VAF 125/348 reads (36%) | called by pindel, varscan2
- ROS1 | c.3653T>C p.F1218S | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- RPL5 | c.883G>C p.A295P | Missense Mutation (SNP) | VAF 68/211 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- RPP25L | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 338/764 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- SEMA5B | c.2390G>A p.R797Q | Missense Mutation (SNP) | VAF 187/757 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEPTIN6 | c.435C>A p.D145E | Missense Mutation (SNP) | VAF 28/578 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC15A3 | c.366_372del p.F123Tfs*63 | Frame Shift Del (DEL) | VAF 162/725 reads (22%) | called by mutect2, pindel, varscan2
- STARD8 | c.431G>T p.S144I | Missense Mutation (SNP) | VAF 45/728 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.021); called by muse, mutect2
- SYNE1 | c.5848G>T p.A1950S (on ENST00000367255 / NM_182961.4; = p.A1957S on NM_033071.3) | Missense Mutation (SNP) | VAF 101/473 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UBR4 | c.9059C>G p.A3020G | Missense Mutation (SNP) | VAF 84/288 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ZBTB7B | c.1163A>C p.K388T (on ENST00000292176; = p.K422T on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/275 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZNF799 | c.1477C>G p.Q493E | Missense Mutation (SNP) | VAF 72/252 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ADAMTS12 | c.3891C>A p.G1297= | Silent (SNP) | VAF 31/482 reads (6%) | catalogued as COSV100710436; called by muse, mutect2
- AGL | c.1656A>G p.V552= | Silent (SNP) | VAF 73/293 reads (25%) | called by muse, mutect2, varscan2
- AVPR1A | c.36G>A p.S12= | Silent (SNP) | VAF 55/360 reads (15%) | catalogued as rs1414515126, COSV54547254; called by muse, mutect2, varscan2
- CACNA1E | c.2433C>A p.L811= | Silent (SNP) | VAF 137/594 reads (23%) | called by muse, mutect2, varscan2
- CCSER1 | c.2316G>A p.A772= | Silent (SNP) | VAF 90/339 reads (27%) | catalogued as rs1397732187; called by muse, mutect2, varscan2
- DNAH11 | c.1857T>C p.C619= | Silent (SNP) | VAF 8/188 reads (4%) | catalogued as rs1361512116; called by muse, mutect2
- GJC2 | c.531G>A p.A177= | Silent (SNP) | VAF 208/758 reads (27%) | catalogued as rs776968941; called by muse, mutect2, varscan2
- HERC1 | c.8082T>C p.L2694= | Silent (SNP) | VAF 114/315 reads (36%) | called by muse, mutect2, varscan2
- KIAA1549L | c.4641C>T p.I1547= (on ENST00000321505; = p.I1844= on NM_012194.3) | Silent (SNP) | VAF 121/382 reads (32%) | catalogued as rs368722488; called by muse, varscan2
- LSR | c.1845C>T p.Y615= (on ENST00000361790; = p.Y596= on NM_015925.6) | Silent (SNP) | VAF 144/554 reads (26%) | called by muse, mutect2, varscan2
- PASK | c.2403C>T p.T801= | Silent (SNP) | VAF 135/466 reads (29%) | catalogued as rs568061248, COSV52153621; called by muse, mutect2, varscan2
- PAX9 | c.726C>T p.N242= | Silent (SNP) | VAF 37/726 reads (5%) | catalogued as rs1055255967; called by muse, mutect2
- PCDHGA4 | c.132G>T p.L44= | Silent (SNP) | VAF 22/554 reads (4%) | called by muse, mutect2
- RYR2 | c.3180C>T p.Y1060= | Silent (SNP) | VAF 32/348 reads (9%) | catalogued as rs398123540, COSV63721277; ClinVar: benign / likely benign / uncertain significance; called by muse, mutect2
- SHANK3 | c.4077C>T p.S1359= | Silent (SNP) | VAF 114/563 reads (20%) | catalogued as rs754778424; called by muse, mutect2, varscan2
- SHCBP1L | c.384C>T p.D128= | Silent (SNP) | VAF 94/399 reads (24%) | catalogued as COSV100840934; called by muse, mutect2, varscan2
- SIPA1 | c.105G>A p.P35= | Silent (SNP) | VAF 226/729 reads (31%) | catalogued as rs768841771; called by muse, mutect2, varscan2
- SLITRK2 | c.912G>A p.P304= | Silent (SNP) | VAF 159/539 reads (29%) | catalogued as rs377471915; called by muse, mutect2, varscan2
- SOX11 | c.426G>A p.A142= | Silent (SNP) | VAF 132/460 reads (29%) | catalogued as rs1435669765; called by mutect2, varscan2
- SPIDR | c.669G>C p.L223= | Silent (SNP) | VAF 44/410 reads (11%) | called by muse, mutect2, varscan2
- SRGAP3 | c.2208G>A p.E736= | Silent (SNP) | VAF 190/310 reads (61%) | called by muse, mutect2, varscan2
- TDRD9 | c.447C>T p.S149= | Silent (SNP) | VAF 65/194 reads (34%) | catalogued as COSV59142753; called by muse, varscan2
- TGFBRAP1 | c.636C>T p.I212= | Silent (SNP) | VAF 104/367 reads (28%) | catalogued as rs772448911, COSV51515853; called by muse, mutect2, varscan2
- USP34 | c.7947G>A p.Q2649= | Silent (SNP) | VAF 89/323 reads (28%) | called by muse, mutect2, varscan2
- ZNF331 | c.1218C>A p.T406= | Silent (SNP) | VAF 92/329 reads (28%) | catalogued as rs764501728; called by muse, mutect2, varscan2
- DEPDC5 | c.2120+126G>A | Intron (SNP) | VAF 65/213 reads (31%) | called by muse, mutect2, varscan2
- FBXL22 | c.354-562G>A | Intron (SNP) | VAF 153/493 reads (31%) | catalogued as rs1425407045; called by muse, mutect2, varscan2
- MGAM | c.4619-2014C>T | Intron (SNP) | VAF 47/359 reads (13%) | catalogued as rs754337224; called by muse, mutect2, varscan2
- OSGIN1 | n.2012C>T | RNA (SNP) | VAF 156/507 reads (31%) | catalogued as rs536349060, COSV59423909; called by muse, mutect2, varscan2
- TFEC | c.-55A>T | 5'UTR (SNP) | VAF 109/439 reads (25%) | called by muse, mutect2, varscan2
- UNC13B | c.762-4654dup | Intron (INS) | VAF 149/427 reads (35%) | called by mutect2, pindel, varscan2
- Z99774.2 | chr22:26670762 G>T | 5'Flank (SNP) | VAF 16/316 reads (5%) | called by muse, mutect2
